Surgical pathology report (de-identified scan), TCGA case TCGA-Y8-A894, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Spectrum Health, specimen TCGA-Y8-A894-01A (Primary Tumor).

[page 1 of 2]
Research Gross Description

female with left renal lesion

Research Dx

CASE SUMMARY FOR NEPHRECTOMY FOR RENAL CELL CARCINOMA:

Procedure: Partial nephrectomy

Specimen laterality: Left

Tumor site: Middle pole

Tumor size: 1.8 cm

Extent of disease: Tumor limited to the kidney

Histologic type: Papillary renal cell carcinoma, type 1

Sarcomatoid features: Not identified

Tumor necrosis: Not identified

Histologic grade (Fuhrman Nuclear Grade): 2

Margins: Negative

Lymphovascular invasion: Not identified

Pathologic staging (pTNM): -

Primary tumor: pT1a (tumor less than 4 cm in greatest dimension, limited to the kidney)

Regional lymph nodes: No lymph nodes are submitted

Number examined: 0

Number involved: Not applicable

Distant metastasis: pM-not applicable

Pathologic findings in nonneoplastic kidney: Peritumoral chronic inflammation; foci of interstitial chronic inflammation with scattered sclerosed glomeruli and arterial nephrosclerosis

Other tumors and/or tumor-like lesions: None

AJCC Staging (7th edition) pT1a pNX pM-not applicable

Research QC

Tumor:

100% tumor nuclei

0% necrosis

0% normal

Normal:

99% kidney, small papillary carcinoma probable floater 1%

Specimen Process Time

Blood draw time:

Plasma frozen time:

Serum frozen time:

Buffy coat frozen time:

Cold ischemia start time:

Formalin fixation start time:

Total cold ischemia time:

Formalin fixation stopped time:

Total formalin fixation time:

ICD-O-3
Carcinoma, papillary renal
cell 8260/3
Site O Kidney NOS 064.9
JW 11/22/13

[page 2 of 2]
Specimen Weight

Normal
1-170 mg, 2-110 mg
Tumor
1-150 mg, 2-130 mg

Specimen Size

Plasma x 3
Serum x 3
Buffy coat x 1

Cryovials x 4
Normal x 2
Tumor x 2
FFPE x 4
Normal x 2
Tumor x 2

Study

Patient Consent

Yes

Source: NCI Genomic Data Commons file 8718c2e1-0ff7-4aa9-8ad6-5959bc53fd5b (TCGA-Y8-A894.7FA3534E-CC88-4B71-8DB6-4E9D0DA17AF0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).